PECGS case C083-000023 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction.
https://portal.gdc.cancer.gov/cases/1a63f8ec-3728-4498-ab92-64d915cd7362

Demographics
Sex at birth: male; Age at index: 35 years; Year of birth: 1987; Education level: Professional or Graduate Degree.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 35.0 years (12,784 days); AJCC clinical stage: Stage IVA; AJCC pathologic stage: Stage IVA; Progression or recurrence: no.

Other clinical attributes
- BMI: 24.95.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: No.

Biospecimens (2 samples)
- Sample C083-000023_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000023_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
